Somatic mutation profile of tumor specimen TCGA-25-2408-01A (aliquot TCGA-25-2408-01A-01W-0799-08) from TCGA case TCGA-25-2408, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G2; Age at diagnosis: 37.3 years (13,606 days).
Specimen TCGA-25-2408-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a0dfa72-b09c-4f3e-b49f-e47cb271baef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-2408-10A (Blood Derived Normal), aliquot TCGA-25-2408-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72f7b9f6-e120-40eb-96a2-52792377ead7

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Del 1, Splice Region 1, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA9 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs756457606, COSV60626563; called by muse, mutect2, varscan2
- CDKN1B | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.94); PolyPhen benign (0.236); catalogued as COSV57431456; called by muse, mutect2, varscan2
- DENND10 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 112/428 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63857885, COSV63858194; called by muse, mutect2, varscan2
- ERC1 | c.2891A>G p.E964G (on ENST00000360905 / NM_178040.4; = p.E936G on NM_178039.4) | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61698928; called by muse, mutect2, varscan2
- HES1 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as rs761011090, COSV51685163; called by muse, mutect2
- KCNH6 | c.2843C>T p.P948L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.069); catalogued as rs576892047, COSV59007062; called by muse, mutect2, varscan2
- NDST2 | c.1265C>T p.T422M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs751982453, COSV55217420; called by muse, mutect2, varscan2
- OR14C36 | c.664A>C p.T222P | Missense Mutation (SNP) | VAF 98/493 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58602601; called by muse, mutect2, varscan2
- PHF3 | c.3561A>T p.P1187= | Splice Region (SNP) | VAF 50/148 reads (34%) | catalogued as COSV50336951; called by muse, mutect2, varscan2
- RAP1GAP | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV51577264; called by muse, mutect2
- TEX26 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 56/148 reads (38%) | catalogued as rs193234818, COSV66840133, COSV66841191; called by muse, mutect2, varscan2
- UACA | c.3056G>C p.S1019T | Missense Mutation (SNP) | VAF 92/290 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV59859179; called by muse, mutect2, varscan2
- ARHGEF7 | c.2041_2052dup p.K681_L684dup (on ENST00000375741 / NM_001113511.2; = p.K503_L506dup on NM_003899.5 and 5 other RefSeq transcripts) | In Frame Ins (INS) | VAF 21/65 reads (32%) | called by mutect2, varscan2
- THAP4 | c.289del p.H97Mfs*16 | Frame Shift Del (DEL) | VAF 10/106 reads (9%) | called by mutect2, pindel
- EFCAB5 | c.3813C>A p.G1271= | Silent (SNP) | VAF 156/482 reads (32%) | catalogued as COSV57935947; called by muse, mutect2, varscan2
- PLEKHG6 | c.498G>A p.L166= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs1254780381, COSV50610484; called by muse, mutect2, varscan2
- RWDD2A | c.354C>A p.L118= | Silent (SNP) | VAF 26/324 reads (8%) | catalogued as COSV99392580; called by muse, mutect2
